Somatic mutation profile of tumor specimen ALCH-AERN-TTP1-A (aliquot ALCH-AERN-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AERN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.0 years (23,728 days).
Specimen ALCH-AERN-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d19b1e57-78e2-437a-b82c-127fcfcc9c8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AERN-NB1-A (Blood Derived Normal), aliquot ALCH-AERN-NB1-A-2-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/030042bf-a79e-40f7-b6fa-421b0bcc73da

The open-access MAF lists 152 somatic variants for this specimen: 96 protein-altering or splice-affecting, 32 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 32, Intron 13, 3'UTR 5, RNA 4, Nonsense Mutation 3, Splice Region 2, 5'UTR 1, In Frame Del 1, 5'Flank 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 199/832 reads (24%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TYR | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs61754393, CM910387, COSV54480810; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.2785C>G p.L929V | Missense Mutation (SNP) | VAF 82/1236 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.205); catalogued as rs750366312, COSV101329992; called by muse, mutect2
- ADGB | c.474T>G p.Y158* | Nonsense Mutation (SNP) | VAF 13/110 reads (12%) | catalogued as COSV58855761; called by muse, mutect2
- AGBL1 | c.1635G>T p.Q545H | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV66871290; called by muse, mutect2
- ANK2 | c.3245C>T p.P1082L | Missense Mutation (SNP) | VAF 48/393 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52171385; called by muse, mutect2, varscan2
- ATP5MPL | c.131G>C p.R44T | Missense Mutation (SNP) | VAF 55/315 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV54603279; called by muse, mutect2, varscan2
- CDCA7 | c.532C>T p.R178C (on ENST00000347703 / NM_145810.3; = p.R257C on NM_031942.5) | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs147594902; called by muse, mutect2, varscan2
- CDK19 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 26/499 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs975083127; called by muse, mutect2
- CSMD1 | c.7774G>T p.G2592C (on ENST00000520002; = p.G2591C on NM_033225.6) | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408540721; called by muse, mutect2, varscan2
- DDX5 | c.41G>C p.R14P | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV56748565; called by muse, mutect2
- DMD | c.4246G>C p.D1416H | Missense Mutation (SNP) | VAF 18/620 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1186095572; called by muse, mutect2
- F8 | c.2121G>T p.W707C | Missense Mutation (SNP) | VAF 20/441 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM061759, COSV64273057; called by muse, mutect2
- FCRLA | c.994C>A p.P332T (on ENST00000367959; = p.P309T on NM_032738.4) | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV52685526; called by muse, mutect2
- GRIN3B | c.2413G>A p.D805N | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs575518840, COSV52261327; called by muse, mutect2
- ITIH5 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs749743981, COSV53669740; called by muse, mutect2
- MEAF6 | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.954); catalogued as rs748640607; called by muse, mutect2, varscan2
- MGAT4C | c.1174dup p.I392Nfs*2 | Frame Shift Ins (INS) | VAF 86/218 reads (39%) | catalogued as rs746398787; called by mutect2, varscan2
- MUC4 | c.9037G>T p.D3013Y | Missense Mutation (SNP) | VAF 22/568 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV57774280; called by muse, mutect2
- NELL1 | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.242); catalogued as COSV54266127; called by muse, mutect2
- NEU2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs760542299, COSV52092700; called by muse, mutect2, varscan2
- OR2Z1 | c.943T>G p.*315Gext*7 | Nonstop Mutation (SNP) | VAF 3/44 reads (7%) | catalogued as COSV60692565; called by muse, mutect2
- OR51G1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs200001303; called by muse, mutect2
- PIK3CA | c.334A>T p.I112F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV55908000; called by muse, mutect2, varscan2
- PSMA3 | c.331-1G>T p.X111_splice | Splice Site (SNP) | VAF 15/175 reads (9%) | catalogued as COSV53617213; called by muse, mutect2
- RAPGEF2 | c.86A>G p.H29R | Missense Mutation (SNP) | VAF 75/312 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs767154170; called by muse, mutect2, varscan2
- RNPEPL1 | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371830036; called by muse, mutect2, varscan2
- RYR2 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs200685968; ClinVar: uncertain significance; called by muse, varscan2
- SLC17A6 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs760965326, COSV99580827; called by muse, mutect2
- SPTA1 | c.6447G>T p.E2149D | Missense Mutation (SNP) | VAF 24/824 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.416); catalogued as COSV63748485; called by muse, mutect2
- THNSL2 | c.268G>C p.V90L | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs1389937739; called by muse, mutect2
- TNR | c.1628G>C p.G543A | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.86); catalogued as rs1388472056, COSV54887701; called by muse, mutect2, varscan2
- TTYH2 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 18/442 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs1230514720; called by muse, mutect2
- TULP3 | c.251A>G p.H84R | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as rs570541745; called by muse, mutect2, varscan2
- ZFC3H1 | c.5185C>G p.R1729G | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV66431911; called by muse, mutect2
- ZNF624 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763354326, COSV60939950; called by muse, mutect2, varscan2
- ACTG2 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- ADCY5 | c.2248G>C p.E750Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADGRL3 | c.1931C>A p.A644D (on ENST00000506720 / NM_001322402.2; = p.A576D on NM_015236.6) | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ALAS2 | c.549G>C p.E183D | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- ASPM | c.7018T>C p.F2340L | Missense Mutation (SNP) | VAF 40/492 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.055); called by muse, mutect2
- ATG16L2 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCOR | c.2015C>T p.S672F | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- C17orf75 | c.783G>C p.M261I | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.018); called by muse, mutect2
- CABS1 | c.728A>G p.D243G | Missense Mutation (SNP) | VAF 40/387 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CACNG7 | c.570+3G>T | Splice Region (SNP) | VAF 18/156 reads (12%) | called by muse, mutect2, varscan2
- CCDC175 | c.1675G>C p.V559L | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.232); called by muse, mutect2
- CPN1 | c.1105A>C p.T369P | Missense Mutation (SNP) | VAF 55/551 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CRTAM | c.301T>G p.Y101D | Missense Mutation (SNP) | VAF 16/490 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DICER1 | c.3344C>T p.S1115L | Missense Mutation (SNP) | VAF 40/345 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLG2 | c.1847A>T p.N616I | Missense Mutation (SNP) | VAF 50/506 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2
- ERCC6L | c.1217T>C p.V406A | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2
- FBXL22 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FGFRL1 | c.1352G>A p.G451E | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- FYB1 | c.891C>A p.S297R | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.168); called by muse, mutect2
- GLI2 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- GRM8 | c.757A>T p.I253F | Missense Mutation (SNP) | VAF 12/396 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.393); called by muse, mutect2
- HGSNAT | c.1798A>G p.K600E | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCND1 | c.1760T>A p.L587Q | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, mutect2
- KIAA0408 | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 24/367 reads (7%) | called by muse, mutect2
- LRRC8B | c.1882A>G p.S628G | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); called by muse, varscan2
- LRRFIP1 | c.1473T>G p.S491R (on ENST00000392000 / NM_001137552.2; = p.S467R on NM_004735.4) | Missense Mutation (SNP) | VAF 23/359 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- MGA | c.8253G>A p.M2751I (on ENST00000219905 / NM_001164273.1; = p.M2542I on NM_001080541.2) | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- MOSPD2 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO9A | c.1555C>G p.L519V | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2
- NBEA | c.3604A>T p.I1202L | Missense Mutation (SNP) | VAF 35/304 reads (12%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBN | c.1367G>A p.R456K | Missense Mutation (SNP) | VAF 38/400 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NEFL | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 97/216 reads (45%) | PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NEK1 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 15/358 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.118); called by muse, mutect2
- NUDCD2 | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2
- OR2AG2 | c.737T>G p.I246S | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- OR2T11 | c.137T>A p.I46N | Missense Mutation (SNP) | VAF 24/657 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- PCNT | c.4718A>T p.N1573I | Missense Mutation (SNP) | VAF 42/822 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.187); called by muse, mutect2
- PGR | c.2740G>T p.A914S | Missense Mutation (SNP) | VAF 48/546 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.018); called by muse, mutect2
- PYGM | c.346C>T p.L116= | Splice Region (SNP) | VAF 25/267 reads (9%) | called by muse, mutect2, varscan2
- RBSN | c.1205A>T p.Q402L | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RDH16 | c.283_290delinsA p.Q95Rfs*5 | Frame Shift Del (DEL) | VAF 18/30 reads (60%) | called by pindel, varscan2*
- RIMS2 | c.4760C>A p.P1587H (on ENST00000666250 / NM_001348490.2; = p.P1158H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- RPL4 | c.87G>C p.K29N | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); called by muse, mutect2
- SLC34A2 | c.89A>T p.D30V | Missense Mutation (SNP) | VAF 65/463 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC47A1 | c.1538G>A p.G513D | Missense Mutation (SNP) | VAF 28/377 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- SPG11 | c.6958A>G p.K2320E | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TACC2 | c.4220A>T p.D1407V | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRAPPC11 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 37/468 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2
- UBR3 | c.1927A>G p.S643G | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.952); called by muse, mutect2
- USP14 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- VAX2 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.297); called by muse, mutect2
- VPS35L | c.2465C>T p.T822I | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.013); called by muse, mutect2
- YJU2 | c.758G>T p.S253I | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ZCCHC12 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- ZCCHC8 | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 15/334 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2
- ZEB2 | c.2842G>C p.D948H | Missense Mutation (SNP) | VAF 13/396 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.401); called by muse, mutect2
- ZFHX3 | c.3113T>C p.V1038A | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ZNF98 | c.453C>A p.N151K | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF99 | c.2451C>A p.Y817* | Nonsense Mutation (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- ZSCAN5B | c.431A>T p.D144V | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); called by muse, mutect2
- ABCA13 | c.7335C>G p.L2445= | Silent (SNP) | VAF 44/504 reads (9%) | called by muse, mutect2
- ACOT7 | c.759C>T p.L253= (on ENST00000377855 / NM_181864.3; = p.L243= on NM_007274.4) | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- AHRR | c.765G>A p.P255= | Silent (SNP) | VAF 24/207 reads (12%) | catalogued as rs371473301; called by muse, varscan2
- AP5M1 | c.1395G>A p.R465= | Silent (SNP) | VAF 22/402 reads (5%) | called by muse, mutect2
- CFH | c.687G>A p.E229= | Silent (SNP) | VAF 24/360 reads (7%) | called by muse, mutect2
- CHL1 | c.972C>T p.H324= (on ENST00000397491 / NM_001253387.1; = p.H340= on NM_006614.4) | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs754600608, COSV56610330; called by muse, varscan2
- CHRM2 | c.1089C>T p.R363= | Silent (SNP) | VAF 21/580 reads (4%) | called by muse, mutect2
- CNTROB | c.132C>A p.L44= | Silent (SNP) | VAF 21/291 reads (7%) | called by muse, mutect2
- COL5A3 | c.945C>G p.L315= | Silent (SNP) | VAF 13/128 reads (10%) | called by muse, mutect2, varscan2
- DISP3 | c.234C>A p.L78= | Silent (SNP) | VAF 29/257 reads (11%) | called by muse, mutect2, varscan2
- DYSF | c.168C>T p.G56= | Silent (SNP) | VAF 19/514 reads (4%) | catalogued as COSV50542066; called by muse, mutect2
- GTF3A | c.930C>G p.L310= | Silent (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- HELB | c.1366C>A p.R456= | Silent (SNP) | VAF 22/286 reads (8%) | catalogued as rs769875630; called by muse, mutect2
- IL9 | c.99C>T p.L33= | Silent (SNP) | VAF 24/219 reads (11%) | called by muse, varscan2
- KAT7 | c.882G>T p.R294= | Silent (SNP) | VAF 24/418 reads (6%) | called by muse, mutect2
- KRTAP10-3 | c.117G>A p.P39= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs371451976; called by muse, mutect2
- KRTAP11-1 | c.390C>T p.V130= | Silent (SNP) | VAF 15/182 reads (8%) | catalogued as COSV60094081, COSV60095691; called by muse, mutect2
- LNPEP | c.1911A>G p.L637= | Silent (SNP) | VAF 46/514 reads (9%) | called by muse, mutect2
- MUC12 | c.13272C>T p.S4424= (on ENST00000379442; = p.S4281= on NM_001164462.1) | Silent (SNP) | VAF 36/988 reads (4%) | called by muse, mutect2
- MYH4 | c.1305C>T p.Y435= | Silent (SNP) | VAF 100/402 reads (25%) | catalogued as rs201920700, COSV55116378; called by muse, mutect2, varscan2
- OR10X1 | c.582C>T p.F194= | Silent (SNP) | VAF 20/354 reads (6%) | called by muse, mutect2
- PCGF1 | c.30G>A p.A10= | Silent (SNP) | VAF 16/164 reads (10%) | catalogued as rs767839542; called by mutect2, varscan2
- PDZD2 | c.7455G>A p.L2485= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV56854914; called by muse, mutect2, varscan2
- PPWD1 | c.432G>A p.E144= | Silent (SNP) | VAF 46/369 reads (12%) | catalogued as rs1184574088; called by muse, mutect2, varscan2
- SCN3B | c.39C>G p.L13= | Silent (SNP) | VAF 28/503 reads (6%) | called by muse, mutect2
- SCN5A | c.5055G>A p.E1685= (on ENST00000333535 / NM_198056.3; = p.E1684= on NM_000335.5) | Silent (SNP) | VAF 16/244 reads (7%) | catalogued as BM1492175; called by muse, mutect2
- SLC6A5 | c.1566C>G p.S522= | Silent (SNP) | VAF 38/588 reads (6%) | catalogued as COSV54225937; called by muse, mutect2
- TACC2 | c.1758T>G p.P586= | Silent (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- TAF5L | c.576C>G p.T192= | Silent (SNP) | VAF 32/466 reads (7%) | catalogued as COSV51083914; called by muse, mutect2
- TMEM259 | c.1296C>T p.V432= | Silent (SNP) | VAF 22/181 reads (12%) | called by muse, varscan2
- WDR11 | c.3420G>A p.V1140= | Silent (SNP) | VAF 58/482 reads (12%) | called by muse, mutect2, varscan2
- WNT1 | c.552C>T p.F184= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- AC079154.1 | n.996C>A | RNA (SNP) | VAF 32/209 reads (15%) | catalogued as rs1362865350; called by muse, mutect2, varscan2
- AC136628.2 | n.1046G>T | RNA (SNP) | VAF 17/140 reads (12%) | called by muse, mutect2, varscan2
- AK2 | c.*3664G>C | 3'UTR (SNP) | VAF 65/774 reads (8%) | called by muse, mutect2
- AP000943.2 | chr11:94740959 C>A | 5'Flank (SNP) | VAF 54/632 reads (9%) | called by muse, mutect2
- BRINP2 | c.461-10T>C | Intron (SNP) | VAF 45/474 reads (9%) | called by muse, mutect2
- CLVS1 | c.-152+90C>A | Intron (SNP) | VAF 7/146 reads (5%) | called by muse, mutect2
- CNIH2 | c.82-807G>A | Intron (SNP) | VAF 156/518 reads (30%) | called by muse, mutect2, varscan2
- CXCL12 | c.*360C>T | 3'UTR (SNP) | VAF 14/172 reads (8%) | catalogued as rs1349050595; called by muse, mutect2
- GNAO1 | c.161+1565G>A | Intron (SNP) | VAF 27/206 reads (13%) | catalogued as rs1214534686, COSV52617237; called by muse, mutect2, varscan2
- INTS11 | c.1403-11C>T | Intron (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- LILRB2 | c.1360+12del | Intron (DEL) | VAF 12/109 reads (11%) | catalogued as rs1225026177; called by mutect2, pindel, varscan2
- LINC01119 | n.1623G>T | RNA (SNP) | VAF 42/390 reads (11%) | catalogued as rs1243439080; called by muse, mutect2, varscan2
- MAX | c.37-74C>G | Intron (SNP) | VAF 19/172 reads (11%) | called by muse, mutect2, varscan2
- NPIPB1P | n.100G>T | RNA (SNP) | VAF 52/646 reads (8%) | called by muse, mutect2
- NRBP2 | c.*169C>A | 3'UTR (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- ODF3 | c.311-65G>C | Intron (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- PAXBP1 | c.*36C>T | 3'UTR (SNP) | VAF 20/549 reads (4%) | catalogued as rs1170023930; called by muse, mutect2
- PCDHGA4 | c.2514+20G>C | Intron (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- PDE1C | c.1892-14501A>G | Intron (SNP) | VAF 49/540 reads (9%) | called by muse, mutect2
- PLOD1 | c.*13G>T | 3'UTR (SNP) | VAF 20/300 reads (7%) | called by muse, mutect2
- PTBP2 | c.-21G>A | 5'UTR (SNP) | VAF 33/207 reads (16%) | catalogued as rs766539552, COSV64624579; called by muse, mutect2, varscan2
- PYCR2 | c.68-11G>A | Intron (SNP) | VAF 27/216 reads (13%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23952G>A | Intron (SNP) | VAF 77/210 reads (37%) | called by muse, mutect2, varscan2
- TTN | c.10303+1377C>G | Intron (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2
